Somatic mutation profile of tumor specimen 0DPBGS from CCDI case PBBZYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 17.0 years (6,207 days).
Specimen 0DPBGS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75af2832-f253-43d2-bb2c-39bd0f47030e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBF9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67f63c5a-c209-44d1-85f6-dcc94ab46047

The open-access MAF lists 14 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 6, Missense Mutation 5, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCOR2 | c.2732C>T p.A911V | Missense Mutation (SNP) | VAF 31/516 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs1361747043, COSV100658121; called by muse, mutect2
- PPM1D | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 40/1450 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV59956164; called by muse, mutect2
- C2CD6 | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 32/1386 reads (2%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2
- OR2AJ1 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 814/1900 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWF | c.7817T>C p.M2606T | Missense Mutation (SNP) | VAF 72/1172 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 90/1554 reads (6%) | catalogued as rs147089589; called by muse, mutect2
- TMEM131L | c.3450A>G p.V1150= | Silent (SNP) | VAF 335/915 reads (37%) | called by muse, mutect2, varscan2
- C1RL | c.72-12C>T | Intron (SNP) | VAF 403/928 reads (43%) | called by muse, mutect2, varscan2
- EPS8L1 | c.430-246G>T | Intron (SNP) | VAF 364/836 reads (44%) | called by muse, mutect2, varscan2
- LGI1 | c.288-74dup | Intron (INS) | VAF 48/343 reads (14%) | called by mutect2, pindel, varscan2
- MED23 | c.2779-34G>T | Intron (SNP) | VAF 16/506 reads (3%) | called by muse, mutect2
- PCDH7 | c.3174+81T>C | Intron (SNP) | VAF 13/380 reads (3%) | called by muse, mutect2
- TFDP1 | c.*61T>A | 3'UTR (SNP) | VAF 262/554 reads (47%) | catalogued as rs1251771860, COSV64741772; called by muse, mutect2, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
